Somatic mutation profile of tumor specimen TCGA-NC-A5HP-01A (aliquot TCGA-NC-A5HP-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HP, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.2 years (25,286 days).
Specimen TCGA-NC-A5HP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfc563d5-0a5f-421d-af3d-89e46973c106.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HP-10A (Blood Derived Normal), aliquot TCGA-NC-A5HP-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc38aa02-a648-4cf1-8549-1a262cd9abd5

The open-access MAF lists 434 somatic variants for this specimen: 322 protein-altering or splice-affecting, 100 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 100, Nonsense Mutation 33, Intron 7, Frame Shift Del 6, Splice Site 4, Splice Region 4, Translation Start Site 3, Frame Shift Ins 3, RNA 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RHOA | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV69041798; called by muse, mutect2, varscan2
- TP53 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.858C>A p.C286* | Nonsense Mutation (SNP) | VAF 38/55 reads (69%) | catalogued as rs778092335, COSV99225095; called by muse, mutect2, varscan2
- ACAN | c.6259C>G p.P2087A | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs1307078400, COSV100716862; called by muse, mutect2, varscan2
- ACCSL | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV101122142; called by muse, mutect2, varscan2
- ACSM5 | c.962C>A p.P321Q | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100088308; called by muse, mutect2, varscan2
- ADAM30 | c.654T>A p.F218L | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV101023742; called by muse, mutect2, varscan2
- ADAM8 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV101291588; called by muse, mutect2, varscan2
- ADGRB3 | c.2857C>A p.L953M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99483201; called by muse, mutect2, varscan2
- ADGRG3 | c.204G>T p.Q68H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); catalogued as rs1376259092, COSV100341995; called by muse, mutect2, varscan2
- AGFG1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100028273; called by muse, mutect2, varscan2
- AHNAK | c.9586G>A p.E3196K | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV57224492; called by muse, mutect2, varscan2
- AL121899.2 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs750527679, COSV67349736, COSV67351744; called by muse, mutect2, varscan2
- ALDH3B1 | c.1116G>A p.Q372= | Splice Region (SNP) | VAF 40/106 reads (38%) | catalogued as COSV99141651; called by muse, mutect2
- ALS2 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs759408917, COSV51890408; called by muse, mutect2, varscan2
- AMER2 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as rs1566015166, COSV100766110; called by muse, mutect2, varscan2
- ANKK1 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100392649; called by muse, mutect2, varscan2
- ANKRD24 | c.1880C>A p.A627D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99516818; called by muse, mutect2, varscan2
- ANKS1A | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 35/134 reads (26%) | catalogued as COSV100831986; called by muse, mutect2, varscan2
- ANO4 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100151628; called by muse, mutect2, varscan2
- ANO4 | c.1438G>A p.E480K (on ENST00000392977 / NM_001286615.2; = p.E445K on NM_178826.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.913); catalogued as COSV54586331; called by muse, mutect2, varscan2
- APOB | c.2245G>T p.D749Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263186; called by muse, mutect2, varscan2
- ARID2 | c.2680C>G p.Q894E | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV100535241, COSV57602154; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100771761; called by muse, mutect2, varscan2
- ASCC1 | c.395-2A>G p.X132_splice (on ENST00000342444 / NM_001369085.1; = p.X104_splice on NM_001198798.2 and 8 other RefSeq transcripts) | Splice Site (SNP) | VAF 30/63 reads (48%) | catalogued as rs1281256224, COSV100403009; called by muse, mutect2, varscan2
- ASPM | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as COSV54137762, COSV99659336; called by muse, mutect2, varscan2
- BAIAP3 | c.3398T>A p.V1133E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV99136108; called by muse, mutect2, varscan2
- BICC1 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99570107; called by muse, mutect2, varscan2
- BRINP3 | c.1035G>A p.W345* | Nonsense Mutation (SNP) | VAF 71/116 reads (61%) | catalogued as COSV100818198; called by muse, mutect2, varscan2
- BRWD3 | c.5129G>T p.G1710V | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.916); catalogued as COSV100955589, COSV64746346; called by muse, mutect2, varscan2
- C11orf71 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.482); catalogued as rs1271301870, COSV100348255; called by muse, mutect2, varscan2
- CACNA1C | c.811A>T p.I271F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100214615; called by mutect2, varscan2
- CAPN6 | c.1623G>T p.L541F | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100136644; called by muse, mutect2, varscan2
- CASP1 | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751267011, COSV100782685; called by muse, mutect2, varscan2
- CASS4 | c.1833C>A p.Y611* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100824506; called by muse, mutect2, varscan2
- CCDC105 | c.1280C>A p.T427K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.033); catalogued as COSV99479698, COSV99479786; called by muse, mutect2
- CCDC141 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV55371699; called by muse, mutect2, varscan2
- CCDC57 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101051768; called by muse, mutect2, varscan2
- CCDC66 | c.1238G>A p.G413E (on ENST00000394672 / NM_001353147.1; = p.G379E on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1296430882, COSV100413588; called by muse, mutect2, varscan2
- CCT8L2 | c.1406G>C p.G469A | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100742531; called by muse, mutect2, varscan2
- CDH10 | c.668C>A p.P223Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV100049804, COSV52604817; called by muse, mutect2, varscan2
- CDH12 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.649); catalogued as COSV101200840; called by muse, mutect2, varscan2
- CDH9 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50253534, COSV99141291; called by muse, mutect2, varscan2
- CDH9 | c.1762G>T p.V588L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99141293; called by muse, mutect2, varscan2
- CEP170 | c.1232A>G p.Q411R | Missense Mutation (SNP) | VAF 158/249 reads (63%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100316286; called by muse, mutect2, varscan2
- CEP63 | c.22A>C p.I8L | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100132504; called by muse, mutect2, varscan2
- CFAP44 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV99868732; called by muse, mutect2, varscan2
- CFAP47 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV99934189; called by muse, mutect2, varscan2
- CFAP47 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99934190; called by muse, mutect2, varscan2
- CFHR4 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 53/73 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV99259378; called by muse, mutect2, varscan2
- CFHR4 | c.164G>T p.C55F (on ENST00000367416 / NM_001201551.2; = p.C56F on NM_006684.5) | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV52230539; called by muse, mutect2
- CFLAR | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs761958596, COSV57939582; called by muse, mutect2, varscan2
- CHAF1A | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as rs1475432762, COSV100010760; called by muse, mutect2, varscan2
- CHI3L1 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 36/200 reads (18%) | catalogued as rs868360435, COSV99703707; called by muse, mutect2, varscan2
- CIT | c.1980G>T p.Q660H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753261617, COSV99948146; called by muse, mutect2, varscan2
- CKAP5 | c.4789A>T p.N1597Y | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100370302; called by muse, mutect2, varscan2
- CLVS1 | c.940A>C p.N314H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); catalogued as COSV100369338; called by muse, mutect2, varscan2
- CNN1 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV99370563; called by muse, mutect2, varscan2
- CNTN3 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV55166251, COSV55180654; called by muse, mutect2, varscan2
- COL11A1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.931); catalogued as COSV100614707; called by muse, mutect2, varscan2
- COL5A2 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV66409166; called by muse, mutect2
- COLGALT1 | c.1418A>C p.Q473P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs1307829046, COSV99394787; called by muse, mutect2, varscan2
- CR1 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as COSV100887347; called by muse, mutect2
- CTNND2 | c.3342A>T p.T1114= | Splice Region (SNP) | VAF 43/120 reads (36%) | catalogued as COSV100470776; called by muse, mutect2, varscan2
- CUBN | c.10487C>T p.S3496F | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100911957; called by muse, mutect2, varscan2
- CYLC2 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV100872337; called by muse, mutect2, varscan2
- CYP39A1 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 111/350 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV99241786, COSV99242232; called by muse, mutect2, varscan2
- CYSLTR2 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.678); catalogued as rs1194008543, COSV99935089; called by muse, mutect2, varscan2
- DCAF12L2 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758433; called by muse, mutect2, varscan2
- DCAF4L2 | c.189C>A p.S63R | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as COSV100150438; called by muse, mutect2, varscan2
- DCAF6 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 15/15 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV99607441; called by mutect2, varscan2
- DEFB110 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.936); catalogued as COSV101182428; called by muse, mutect2, varscan2
- DEFB110 | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV101182429; called by muse, mutect2, varscan2
- DGAT2 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV99929458; called by muse, mutect2, varscan2
- DGKB | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99335810; called by muse, mutect2, varscan2
- DHX38 | c.3125G>T p.R1042L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51699294, COSV99194178; called by muse, mutect2, varscan2
- DMRTC2 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV99523279; called by muse, mutect2, varscan2
- DNAH7 | c.10771G>A p.E3591K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100413596; called by muse, mutect2, varscan2
- DNAI1 | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1360208525, COSV54283300, COSV99646505; called by muse, mutect2, varscan2
- DNAJC3 | c.1129C>G p.R377G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100953246; called by muse, mutect2, varscan2
- DOCK7 | c.2930G>T p.G977V (on ENST00000635253 / NM_001367561.1; = p.G946V on NM_033407.3) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV99222401; called by muse, mutect2, varscan2
- DUSP22 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100739334; called by muse, mutect2, varscan2
- DUSP22 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as COSV100739335, COSV60528884; called by muse, mutect2, varscan2
- DYRK4 | c.1063dup p.R355Kfs*16 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | catalogued as rs768937539; called by mutect2, varscan2
- DZIP1 | c.580A>T p.K194* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100713988; called by muse, mutect2, varscan2
- EFEMP1 | c.1460T>C p.I487T | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV100816700; called by muse, mutect2, varscan2
- EML1 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV51748790, COSV99214373; called by muse, mutect2, varscan2
- EP400 | c.5636G>A p.R1879H | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.9); catalogued as rs376569991, COSV57786710; called by muse, mutect2, varscan2
- EPB41L3 | c.2198C>G p.T733S | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1249736999, COSV100548030; called by muse, mutect2, varscan2
- EPHB3 | c.839A>T p.K280M | Missense Mutation (SNP) | VAF 141/205 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV100382752; called by muse, mutect2, varscan2
- EPPK1 | c.5227C>G p.L1743V | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV101599721, COSV73261216; called by muse, mutect2, varscan2
- F10 | c.192C>A p.Y64* | Nonsense Mutation (SNP) | VAF 19/147 reads (13%) | catalogued as COSV100979130, COSV100979190; called by muse, mutect2, varscan2
- F13B | c.1172A>G p.E391G | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1206081675, COSV66373348; called by muse, mutect2
- FAM135B | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99417802; called by muse, mutect2, varscan2
- FAM135B | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as COSV99417805; called by muse, mutect2, varscan2
- FAM135B | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as COSV52702509, COSV52723712; called by muse, mutect2, varscan2
- FAM169A | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100998288, COSV65846491; called by muse, mutect2, varscan2
- FAM180A | c.360A>T p.K120N | Missense Mutation (SNP) | VAF 97/154 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100647205; called by muse, mutect2, varscan2
- FAM47A | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100649677; called by muse, mutect2, varscan2
- FAM71B | c.716A>T p.H239L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100261725; called by muse, mutect2, varscan2
- FAT1 | c.11526C>G p.Y3842* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV101498752; called by muse, mutect2, varscan2
- FAT4 | c.1828G>T p.G610W | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs374235705; called by muse, mutect2, varscan2
- FAT4 | c.8321G>T p.R2774M | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100627062; called by muse, mutect2, varscan2
- FAT4 | c.11740G>T p.G3914C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58711047; called by muse, mutect2, varscan2
- FBN2 | c.7849G>A p.E2617K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99324378; called by muse, mutect2, varscan2
- FLG | c.8569C>A p.R2857S | Missense Mutation (SNP) | VAF 469/2287 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100910389, COSV64247348; called by muse, mutect2, varscan2
- FLNA | c.1675C>G p.Q559E | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.098); catalogued as COSV100774239; called by muse, mutect2
- FNDC1 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99794707; called by muse, mutect2, varscan2
- FSCB | c.950A>T p.Q317L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100468776; called by muse, mutect2, varscan2
- GBP1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs576498400, COSV65083665; called by muse, mutect2, varscan2
- GFRA1 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.947); catalogued as COSV100815381, COSV100816376; called by muse, mutect2, varscan2
- GPR155 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs768603525, COSV99789620; called by muse, mutect2
- GPR63 | c.1171A>C p.K391Q | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.243); catalogued as COSV100013094; called by muse, mutect2
- GRIN3A | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100701332; called by muse, mutect2, varscan2
- GTSF1L | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1159605504, COSV100883896; called by muse, mutect2, varscan2
- GUCY1A2 | c.1879G>T p.V627F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465561534, COSV99972344; called by muse, mutect2, varscan2
- GXYLT1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772909761, COSV55140978, COSV99787694; called by muse, mutect2, varscan2
- HCN1 | c.2636C>G p.P879R | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.021); catalogued as COSV100298038, COSV57538566; called by muse, mutect2, varscan2
- HERC1 | c.7168G>T p.A2390S | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as COSV101496287, COSV71249455; called by muse, mutect2, varscan2
- HIVEP1 | c.6125A>T p.D2042V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.972); catalogued as COSV101044558; called by muse, mutect2, varscan2
- HKDC1 | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV100664335; called by muse, mutect2
- HLCS | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100357770; called by muse, mutect2, varscan2
- HOXA2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99760963; called by muse, mutect2, varscan2
- IGSF8 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100081448; called by muse, mutect2, varscan2
- INHBA | c.636C>A p.D212E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs149369067, COSV99637020; called by muse, mutect2, varscan2
- INSM2 | c.1550C>G p.S517C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as rs1418777965, COSV51880145; called by muse, mutect2, varscan2
- INTS2 | c.2110G>T p.G704* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99247652; called by mutect2, varscan2
- IQGAP1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs570821440, COSV99184847; called by muse, mutect2, varscan2
- ITGAM | c.2228T>A p.L743* (on ENST00000648685 / NM_001145808.2; = p.L742* on NM_000632.4) | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99791664; called by muse, mutect2, varscan2
- ITGB3 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | catalogued as COSV101457501, COSV71385189; called by muse, mutect2, varscan2
- ITIH2 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100623120; called by muse, mutect2, varscan2
- JHY | c.1949A>T p.Y650F | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as COSV99912597; called by muse, mutect2, varscan2
- KBTBD6 | c.1454A>T p.Y485F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.301); catalogued as COSV101068677; called by muse, mutect2, varscan2
- KIAA2026 | c.916G>C p.A306P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101198800; called by muse, varscan2
- KIF13A | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403819560, COSV99433402; called by muse, mutect2, varscan2
- KIF26B | c.4581T>A p.H1527Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100831503; called by muse, mutect2, varscan2
- KIFAP3 | c.710G>T p.W237L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100846669; called by muse, mutect2, varscan2
- KIZ | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851791; called by muse, mutect2, varscan2
- KL | c.2902A>C p.T968P | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1260157369, COSV101198969; called by muse, mutect2, varscan2
- KLHL38 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100384223; called by muse, mutect2, varscan2
- KLHL4 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100909037; called by muse, mutect2, varscan2
- KLRG1 | c.240G>C p.M80I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56943332, COSV99868029; called by muse, mutect2, varscan2
- KPNA4 | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1315891433, COSV100514938; called by muse, mutect2, varscan2
- KRTAP19-6 | c.22T>C p.Y8H | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as rs1277656916, COSV100473761; called by muse, mutect2, varscan2
- KRTAP21-1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 96/181 reads (53%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.799); catalogued as rs760539581, COSV100624886, COSV100624964; called by muse, mutect2, varscan2
- LEP | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 75/121 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.774); catalogued as COSV100451328; called by muse, mutect2, varscan2
- LILRB2 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.678); catalogued as COSV100078930, COSV58743817; called by muse, mutect2, varscan2
- LIPF | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV99490105; called by muse, mutect2, varscan2
- LMO1 | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100230742; called by muse, mutect2, varscan2
- LRIG3 | c.2753T>C p.F918S | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV100292376; called by muse, mutect2, varscan2
- LTBP1 | c.864-1G>T p.X288_splice | Splice Site (SNP) | VAF 38/91 reads (42%) | catalogued as COSV100616143, COSV63184131; called by muse, mutect2, varscan2
- MAMLD1 | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.147); catalogued as COSV99475465; called by muse, mutect2, varscan2
- MAP4K3 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.911); catalogued as COSV99809823; called by muse, mutect2, varscan2
- MAST2 | c.197G>T p.S66I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100787774; called by muse, mutect2, varscan2
- MDGA2 | c.2138G>T p.W713L (on ENST00000399232 / NM_001113498.2; = p.W415L on NM_182830.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.844); catalogued as COSV100636141; called by muse, mutect2, varscan2
- MED13L | c.1569G>T p.R523S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV99927626; called by muse, mutect2, varscan2
- MED23 | c.1846C>T p.Q616* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100644703; called by muse, mutect2, varscan2
- MEP1B | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328599, COSV99329152; called by muse, mutect2, varscan2
- MFGE8 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99183932; called by muse, mutect2, varscan2
- MNS1 | c.564T>A p.Y188* | Nonsense Mutation (SNP) | VAF 51/136 reads (38%) | catalogued as COSV99549345; called by muse, mutect2, varscan2
- MRC2 | c.2780G>A p.C927Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329178018, COSV100315711; called by muse, mutect2, varscan2
- MSH6 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.376); catalogued as COSV99314867; called by muse, mutect2, varscan2
- MTNR1A | c.568G>C p.A190P | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100208056; called by muse, mutect2, varscan2
- MUC16 | c.27862C>T p.P9288S | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.047); catalogued as COSV101197739; called by muse, mutect2, varscan2
- NAB2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.972); catalogued as COSV100272449, COSV55665987; called by muse, mutect2, varscan2
- NALCN | c.4759C>A p.Q1587K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV99212736; called by muse, mutect2, varscan2
- NBEA | c.8458C>T p.P2820S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV59791433; called by muse, mutect2, varscan2
- NCKAP5 | c.4001G>T p.S1334I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV100489676; called by muse, mutect2, varscan2
- NES | c.1529C>A p.A510D | Missense Mutation (SNP) | VAF 168/265 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100957720, COSV63960454; called by muse, mutect2, varscan2
- NEUROD4 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV54470599; called by muse, mutect2, varscan2
- NEXN | c.1419_1421del p.R475del | In Frame Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs794729091; called by pindel, varscan2
- NFE2L3 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as COSV50236940, COSV99283428; called by muse, mutect2, varscan2
- NLRP14 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | catalogued as COSV100204454, COSV55070057; called by muse, mutect2, varscan2
- NR1H4 | c.269G>T p.W90L (on ENST00000551379 / NM_001206993.2; = p.W80L on NM_005123.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.621); catalogued as COSV99499926; called by muse, mutect2, varscan2
- NTRK1 | c.1907C>A p.A636E | Missense Mutation (SNP) | VAF 65/87 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV100693092, COSV62328714; called by muse, mutect2, varscan2
- NUP160 | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 34/130 reads (26%) | catalogued as COSV101021226; called by muse, mutect2, varscan2
- OBSCN | c.13950G>T p.E4650D | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV99471492; called by muse, mutect2, varscan2
- OMD | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100979008; called by muse, mutect2, varscan2
- OR10AG1 | c.19G>T p.G7W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100399967; called by muse, mutect2, varscan2
- OR11H4 | c.516C>A p.Y172* | Nonsense Mutation (SNP) | VAF 162/256 reads (63%) | catalogued as COSV100197354; called by muse, mutect2, varscan2
- OR11L1 | c.314T>A p.V105E | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.573); catalogued as COSV100869374; called by mutect2, varscan2
- OR13J1 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100940740; called by muse, mutect2
- OR1Q1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs747130318, COSV99939158; called by muse, mutect2, varscan2
- OR2A14 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 186/297 reads (63%) | catalogued as rs571103587, COSV101376439, COSV68718484; called by muse, mutect2, varscan2
- OR2M4 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 98/152 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV100140937, COSV60707861; called by muse, mutect2, varscan2
- OR2T27 | c.379T>A p.C127S | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV100788093; called by muse, mutect2, varscan2
- OR2W3 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV64457369; called by muse, mutect2, varscan2
- OR52N2 | c.189C>G p.Y63* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as COSV100396021; called by muse, mutect2, varscan2
- OR5D13 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100686654, COSV62332645; called by muse, mutect2, varscan2
- OR5D14 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100162061; called by muse, mutect2
- OR5D16 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV101003809, COSV65722028; called by muse, mutect2, varscan2
- OR5T3 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100282651; called by muse, mutect2, varscan2
- OR5V1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV101011074; called by muse, mutect2, varscan2
- OR6F1 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.129); catalogued as COSV100128874; called by muse, mutect2, varscan2
- OTOF | c.3511C>A p.L1171M (on ENST00000272371 / NM_194248.3; = p.L424M on NM_004802.4) | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99716290; called by muse, mutect2, varscan2
- P2RY14 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV56379720, COSV99851209; called by muse, mutect2, varscan2
- PABPC5 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 34/50 reads (68%) | catalogued as COSV100442052, COSV57040233; called by muse, mutect2, varscan2
- PARP11 | c.533G>T p.W178L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99958681; called by muse, mutect2, varscan2
- PCDH15 | c.4306C>G p.P1436A | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV100214050, COSV57405736; called by muse, mutect2, varscan2
- PCDHB11 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53381183, COSV99503553; called by muse, mutect2, varscan2
- PCSK4 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV99960539; called by muse, mutect2, varscan2
- PDZRN4 | c.854A>G p.K285R (on ENST00000402685 / NM_001164595.2; = p.K27R on NM_013377.4) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100113438; called by muse, mutect2, varscan2
- PEG3 | c.2928G>T p.E976D | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV99686893; called by muse, mutect2, varscan2
- PKHD1 | c.8555G>T p.G2852V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100580825; called by muse, mutect2
- PLCH1 | c.4891A>T p.T1631S (on ENST00000340059 / NM_001130960.2; = p.T1623S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100395389; called by muse, mutect2, varscan2
- PLEKHH2 | c.1841G>T p.S614I | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs779393457, COSV99174270; called by muse, mutect2, varscan2
- PLIN5 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100117065; called by muse, mutect2, varscan2
- PLS1 | c.1884A>G p.I628M | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100537921; called by muse, mutect2, varscan2
- PLXNB2 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100833817; called by muse, mutect2, varscan2
- POM121 | c.1229G>T p.R410L (on ENST00000434423; = p.R145L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/446 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99987435; called by muse, mutect2, varscan2
- POSTN | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65712138; called by muse, mutect2, varscan2
- POSTN | c.1592G>C p.W531S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV101123237; called by muse, mutect2, varscan2
- PPFIA3 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs1309605677, COSV100494641; called by muse, mutect2, varscan2
- PRF1 | c.1117C>A p.R373S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as COSV100942508; called by muse, mutect2, varscan2
- PRKCI | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | catalogued as COSV99855601; called by muse, mutect2, varscan2
- PRRC2B | c.2212A>T p.I738F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100621343; called by muse, mutect2, varscan2
- PRSS55 | c.41C>A p.T14K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs201824405, COSV100153591, COSV100153630; called by muse, mutect2, varscan2
- PRUNE2 | c.3958G>T p.G1320C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV100944177; called by muse, mutect2, varscan2
- RAB11FIP1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 123/222 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs774399623, COSV54763289, COSV99769616; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1603G>T p.V535L | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99241558; called by muse, varscan2
- RAB40C | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.194); catalogued as COSV50194144, COSV99937490; called by muse, mutect2, varscan2
- RARG | c.1017A>G p.G339= | Splice Region (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100553246, COSV58432917; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RASSF9 | c.476G>C p.R159T | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100771169, COSV63432632; called by muse, mutect2, varscan2
- RDH8 | c.364C>A p.L122I (on ENST00000651512; = p.L102I on NM_015725.4) | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV99408491; called by muse, mutect2, varscan2
- RGS7 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100463895; called by muse, mutect2, varscan2
- RHCE | c.554G>T p.W185L | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.71); catalogued as COSV99603682; called by muse, mutect2, varscan2
- RIPOR2 | c.198del p.E68Sfs*14 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as COSV52417890; called by mutect2, pindel, varscan2
- RNF213 | c.10075C>G p.L3359V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100299485; called by muse, mutect2, varscan2
- RYR1 | c.2343C>A p.S781R | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614203, COSV100616225; called by muse, mutect2, varscan2
- SAG | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1054469221, COSV101300632; called by muse, mutect2, varscan2
- SALL3 | c.2290G>C p.G764R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101609918, COSV73305972; called by muse, mutect2, varscan2
- SAP130 | c.1180A>T p.T394S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.183); catalogued as COSV99384023; called by muse, mutect2, varscan2
- SCAF11 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780798244, COSV101014030; called by muse, mutect2, varscan2
- SCN4A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV101438294; called by muse, mutect2, varscan2
- SDK1 | c.4136G>T p.G1379V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268662; called by muse, mutect2, varscan2
- SELENBP1 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100923569; called by muse, mutect2
- SERAC1 | c.1565A>G p.N522S | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as rs376858726; called by muse, mutect2, varscan2
- SERPINA11 | c.1187G>T p.R396M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100593917; called by muse, mutect2, varscan2
- SERPINA11 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.665); catalogued as COSV100593918, COSV100594176; called by muse, mutect2, varscan2
- SERPINA5 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100291406; called by muse, mutect2, varscan2
- SERPINB8 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV99728895; called by muse, mutect2, varscan2
- SH3TC2 | c.974A>T p.N325I | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100101088; called by muse, mutect2, varscan2
- SHCBP1L | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); catalogued as COSV100840917; called by muse, mutect2, varscan2
- SIDT1 | c.1891A>T p.I631F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV99332965; called by muse, mutect2, varscan2
- SLAMF1 | c.780G>C p.L260F | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1339919120, COSV52497570, COSV52502056, COSV99348870; called by muse, mutect2, varscan2
- SLC18A3 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1289658180, COSV100339595; called by muse, mutect2, varscan2
- SLC25A52 | c.98C>G p.P33R (on ENST00000672005; = p.P23R on NM_001034172.4) | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99329330; called by muse, mutect2, varscan2
- SLC7A11 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.73); PolyPhen benign (0.17); catalogued as COSV99762855; called by muse, mutect2, varscan2
- SLC8A2 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV99369579; called by muse, mutect2, varscan2
- SOX5 | c.284A>T p.N95I | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100505667, COSV58617511; called by muse, mutect2, varscan2
- SPHKAP | c.3824A>T p.Q1275L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.323); catalogued as COSV60885383, COSV60889093; called by muse, mutect2, varscan2
- SPRTN | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 11/117 reads (9%) | catalogued as COSV50478899; called by muse, mutect2
- SRGAP1 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV100754175; called by muse, mutect2, varscan2
- STAT4 | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100635933; called by muse, mutect2, varscan2
- STPG4 | c.465G>C p.R155S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99681172; called by muse, mutect2, varscan2
- STX10 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1227350430, COSV99460018; called by muse, mutect2, varscan2
- STXBP4 | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100177897; called by muse, mutect2, varscan2
- SYNE1 | c.23209A>T p.T7737S (on ENST00000367255 / NM_182961.4; = p.T7666S on NM_033071.3) | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99551009; called by muse, mutect2, varscan2
- SYT9 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV100607371; called by muse, mutect2, varscan2
- TAAR9 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1373828970, COSV101453276; called by muse, mutect2, varscan2
- TBC1D13 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99804227; called by muse, mutect2, varscan2
- TBX22 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100960575; called by muse, mutect2, varscan2
- TBX4 | c.1023C>T p.D341= | Splice Region (SNP) | VAF 11/36 reads (31%) | catalogued as rs1302034953, COSV53608212, COSV53609392; called by muse, mutect2, varscan2
- TCF12 | c.826-2A>G p.X276_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as CS156038, COSV99975775; called by muse, mutect2
- TCF21 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52818022, COSV99399487; called by muse, varscan2
- TECTA | c.2835G>C p.Q945H | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.947); catalogued as COSV50732287, COSV99878324; called by muse, mutect2
- TLL1 | c.2969C>A p.T990K | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99285830; called by muse, mutect2, varscan2
- TM7SF3 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV100544595; called by muse, mutect2, varscan2
- TMEM202 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100499090; called by muse, mutect2, varscan2
- TMEM72 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 103/293 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101273478; called by muse, mutect2, varscan2
- TMTC1 | c.2273C>G p.S758* (on ENST00000539277 / NM_001193451.2; = p.S650* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as COSV55478837, COSV99758502; called by muse, mutect2, varscan2
- TNFRSF21 | c.1279G>T p.G427* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99729016; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3602G>C p.R1201T | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as COSV100835756, COSV64100258; called by muse, mutect2, varscan2
- TNXB | c.6774G>T p.E2258D (on ENST00000647633; = p.E2011D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100925665; called by muse, mutect2
- TOGARAM1 | c.3129G>C p.K1043N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100817730; called by muse, mutect2
- TRAF7 | c.540G>C p.Q180H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100398973; called by muse, mutect2, varscan2
- TRPV5 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as COSV99520029; called by muse, mutect2, varscan2
- TTC21A | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV100086814; called by muse, mutect2, varscan2
- TTC38 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101123844; called by muse, mutect2, varscan2
- TTN | c.65030C>A p.A21677D (on ENST00000591111; = p.A14253D on NM_003319.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV59886659, COSV60247842; called by muse, mutect2, varscan2
- TTN | c.6118C>A p.H2040N (on ENST00000591111; = p.H1994N on NM_003319.4) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | PolyPhen probably damaging (0.991); catalogued as COSV100591391, COSV60364248; called by muse, mutect2, varscan2
- TUBA3C | c.419G>C p.S140T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV101262743; called by muse, mutect2, varscan2
- TUSC3 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 24/40 reads (60%) | catalogued as rs868472774, COSV101140155; called by muse, mutect2, varscan2
- ULK1 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100416441; called by muse, mutect2, varscan2
- USP15 | c.2793G>C p.Q931H (on ENST00000280377 / NM_001351159.2; = p.Q902H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV54797800; called by muse, mutect2, varscan2
- USPL1 | c.2258A>T p.K753M | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99686981; called by muse, mutect2, varscan2
- UTRN | c.3569A>G p.K1190R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV100839427; called by muse, mutect2, varscan2
- VCPIP1 | c.941G>T p.S314I | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100125281; called by muse, mutect2, varscan2
- VENTX | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV100383981; called by muse, mutect2, varscan2
- VGLL3 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101051850; called by muse, mutect2, varscan2
- VGLL4 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV99809091; called by muse, mutect2, varscan2
- VPS13D | c.12194T>C p.L4065P | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99165339; called by muse, mutect2, varscan2
- VRTN | c.1924G>T p.V642L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99832086; called by muse, mutect2, varscan2
- VWA8 | c.2464G>T p.V822F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99863469; called by muse, mutect2, varscan2
- WDR6 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100556111; called by muse, mutect2, varscan2
- WIF1 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99682511; called by muse, mutect2
- WNT10B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV56405882, COSV99975709; called by muse, mutect2, varscan2
- WSCD2 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99773947; called by muse, mutect2, varscan2
- YIPF5 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV99187885; called by muse, mutect2, varscan2
- ZFHX4 | c.3702G>T p.M1234I | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV99255032; called by muse, mutect2, varscan2
- ZNF254 | c.1654G>T p.G552C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100741474; called by muse, mutect2, varscan2
- ZNF513 | c.1132C>G p.H378D | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99277219; called by muse, mutect2
- ZNF534 | c.705C>G p.I235M (on ENST00000332323 / NM_001143939.3; = p.I222M on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs761530873, COSV56516889, COSV56521858; called by muse, mutect2, varscan2
- ZNF592 | c.2602A>T p.M868L | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100245638; called by muse, mutect2, varscan2
- ZNF792 | c.1601A>T p.Y534F | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV101289667; called by muse, mutect2, varscan2
- ZNF813 | c.1051G>T p.G351* | Nonsense Mutation (SNP) | VAF 50/107 reads (47%) | catalogued as COSV101124666; called by muse, mutect2, varscan2
- ZNF813 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101124667; called by muse, mutect2, varscan2
- ZNF99 | c.2383G>T p.G795C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV101233654, COSV68056316; called by muse, mutect2
- ZXDA | c.979del p.L327Cfs*25 | Frame Shift Del (DEL) | VAF 17/33 reads (52%) | catalogued as COSV62388524; called by mutect2, pindel, varscan2
- BOP1 | c.1141G>C p.V381L | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.56); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CARF | c.952_953+7del p.X318_splice | Splice Site (DEL) | VAF 23/101 reads (23%) | called by mutect2, pindel, varscan2
- IGHA1 | c.574T>A p.C192S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); called by muse, mutect2
- MDM2 | c.402_405del p.H134Qfs*73 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- MEIOC | c.803dup p.N268Kfs*11 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- PNLIP | c.512del p.G171Vfs*35 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.2659G>T p.G887W | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1L1 | c.767dup p.T257Dfs*25 | Frame Shift Ins (INS) | VAF 18/39 reads (46%) | called by pindel, varscan2
- RP1L1 | c.763_764del p.P255Kfs*26 | Frame Shift Del (DEL) | VAF 25/47 reads (53%) | called by mutect2, varscan2*
- TRAV3 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- UBE2G2 | c.491del p.G164Dfs*60 | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- AOC1 | c.336C>A p.T112= | Silent (SNP) | VAF 88/129 reads (68%) | catalogued as COSV100710568; called by muse, mutect2, varscan2
- ARGLU1 | c.231C>T p.S77= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100639737; called by muse, mutect2, varscan2
- C1orf52 | c.450A>G p.P150= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs937415030, COSV99640860; called by muse, mutect2, varscan2
- CA5A | c.577C>T p.L193= | Silent (SNP) | VAF 94/241 reads (39%) | catalogued as COSV99990345; called by muse, mutect2, varscan2
- CACNA1C | c.6195C>G p.S2065= (on ENST00000399634 / NM_001167625.1; = p.S1994= on NM_000719.7) | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100214619; called by muse, mutect2, varscan2
- CD1D | c.663G>T p.L221= | Silent (SNP) | VAF 25/210 reads (12%) | catalogued as COSV100939527; called by muse, mutect2, varscan2
- CDC42EP3 | c.345C>G p.S115= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as rs181504307, COSV99767734; called by muse, mutect2, varscan2
- CDH10 | c.540G>T p.V180= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100049806; called by muse, mutect2, varscan2
- CENPF | c.8004A>G p.T2668= | Silent (SNP) | VAF 51/79 reads (65%) | catalogued as rs1414317484, COSV100871447; called by muse, mutect2, varscan2
- COL6A6 | c.4749T>A p.P1583= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100649700, COSV62029880; called by muse, mutect2, varscan2
- COX15 | c.471C>T p.R157= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99186692; called by muse, mutect2, varscan2
- CPB1 | c.30G>A p.V10= | Silent (SNP) | VAF 65/99 reads (66%) | catalogued as rs764912411, COSV99294062; called by muse, mutect2, varscan2
- CXXC5 | c.778C>A p.R260= | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as COSV100210514; called by muse, mutect2, varscan2
- DAGLA | c.372C>A p.T124= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV99943892; called by muse, mutect2, varscan2
- DIAPH1 | c.3261T>C p.V1087= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99525678; called by muse, mutect2
- DLL4 | c.2004T>G p.S668= | Silent (SNP) | VAF 93/228 reads (41%) | catalogued as COSV99989551; called by muse, mutect2, varscan2
- E2F8 | c.837G>T p.V279= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100001250; called by muse, mutect2, varscan2
- ECEL1 | c.405G>T p.L135= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1959C>T p.F653= | Silent (SNP) | VAF 88/125 reads (70%) | catalogued as COSV100668326, COSV62571229; called by muse, mutect2, varscan2
- EFCAB3 | c.1059C>G p.L353= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs759730164, COSV100540003, COSV100540500; called by muse, mutect2, varscan2
- FAM107A | c.45G>C p.L15= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV100723906; called by muse, mutect2, varscan2
- FAM220A | c.330A>G p.P110= | Silent (SNP) | VAF 67/121 reads (55%) | catalogued as COSV100510720; called by muse, mutect2, varscan2
- FSHR | c.1086C>T p.Y362= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV100436407; called by muse, mutect2, varscan2
- GALNT13 | c.880C>T p.L294= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV101221958, COSV67231842; called by muse, mutect2, varscan2
- GALNT16 | c.621C>G p.L207= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as COSV100545664; called by muse, mutect2
- GLYAT | c.360C>A p.A120= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV99557040; called by muse, mutect2, varscan2
- GLYAT | c.279A>G p.P93= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs766578124, COSV99557043; called by muse, mutect2, varscan2
- GP2 | c.804G>A p.E268= (on ENST00000381362 / NM_001007240.3; = p.E265= on NM_001502.4) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs978533153, COSV100221209; called by muse, mutect2, varscan2
- GPR87 | c.630G>A p.V210= | Silent (SNP) | VAF 67/237 reads (28%) | catalogued as COSV99608642; called by muse, mutect2, varscan2
- H3C12 | c.21A>T p.T7= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV58152119; called by muse, mutect2, varscan2
- HIRIP3 | c.1623C>T p.D541= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99662792; called by muse, mutect2, varscan2
- HOXC12 | c.837C>G p.L279= | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as COSV99678621; called by muse, mutect2, varscan2
- INSC | c.303G>T p.L101= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV101088681; called by muse, mutect2, varscan2
- IPO5 | c.894C>T p.T298= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99846915; called by muse, mutect2, varscan2
- ITPRID1 | c.2484C>A p.V828= | Silent (SNP) | VAF 75/146 reads (51%) | catalogued as COSV60083601; called by muse, mutect2, varscan2
- KCNA6 | c.567C>A p.V189= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV99768268; called by muse, mutect2, varscan2
- KCNN2 | c.1437G>A p.L479= (on ENST00000264773; = p.L691= on NM_021614.4) | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs779338302, COSV99298596; called by muse, mutect2, varscan2
- KIAA1210 | c.3312A>G p.P1104= | Silent (SNP) | VAF 86/126 reads (68%) | catalogued as COSV101273888; called by muse, mutect2, varscan2
- KIF13A | c.2517G>T p.V839= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV99433394; called by muse, mutect2, varscan2
- KIF24 | c.1812G>A p.T604= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs754589269, COSV100799082; called by muse, mutect2, varscan2
- KLHL32 | c.1651T>C p.L551= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100987074; called by muse, mutect2, varscan2
- LHFPL1 | c.492G>T p.R164= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as COSV100914416; called by muse, mutect2, varscan2
- LMX1A | c.1044G>T p.L348= | Silent (SNP) | VAF 134/194 reads (69%) | catalogued as COSV99671510; called by muse, mutect2, varscan2
- LRRK2 | c.5004G>T p.L1668= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs201698837; called by muse, mutect2
- MACIR | c.36C>G p.T12= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100174604; called by muse, mutect2, varscan2
- MAGEB16 | c.693G>A p.L231= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV101303267; called by muse, mutect2, varscan2
- MAP2 | c.4137C>T p.D1379= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs777404452, COSV52282162; called by muse, mutect2, varscan2
- MKI67 | c.9186G>C p.A3062= | Silent (SNP) | VAF 55/165 reads (33%) | catalogued as COSV100896066, COSV64072744, COSV64073762; called by muse, mutect2, varscan2
- MMP2 | c.123C>T p.V41= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99527349; called by muse, mutect2, varscan2
- NAV3 | c.3159C>A p.P1053= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV57094649, COSV99886246; called by muse, mutect2, varscan2
- NDN | c.384C>A p.V128= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV100086184; called by muse, mutect2, varscan2
- NETO2 | c.1146C>T p.T382= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs139939849; called by muse, mutect2, varscan2
- NPHS1 | c.2733C>A p.A911= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV100799562; called by muse, mutect2, varscan2
- NRG3 | c.237G>T p.L79= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100930420; called by muse, mutect2, varscan2
- NRK | c.1878A>C p.T626= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as COSV99686428; called by muse, mutect2, varscan2
- NUTF2 | c.309C>T p.F103= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV99534159; called by muse, mutect2, varscan2
- NXPE4 | c.225C>A p.I75= | Silent (SNP) | VAF 102/282 reads (36%) | catalogued as rs1565333719, COSV100970283; called by muse, mutect2, varscan2
- OLFM3 | c.972C>A p.A324= (on ENST00000338858 / NM_001288821.1; = p.A304= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100128799; called by muse, mutect2, varscan2
- OR4K17 | c.348C>T p.V116= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as rs778348253, COSV100210457; called by muse, mutect2, varscan2
- OR8D4 | c.78C>A p.P26= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100361688, COSV100361868; called by muse, mutect2, varscan2
- OR8H2 | c.435C>A p.I145= | Silent (SNP) | VAF 69/238 reads (29%) | catalogued as COSV100542108, COSV57944744; called by muse, mutect2, varscan2
- PAX1 | c.481C>T p.L161= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV101270184, COSV68271029, COSV68271784; called by muse, mutect2, varscan2
- PCDHA13 | c.1053C>T p.T351= | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as COSV56509482; called by muse, mutect2, varscan2
- PDCL3 | c.387G>A p.L129= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV99959414; called by muse, mutect2, varscan2
- PDE6H | c.96C>A p.R32= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99843918; called by muse, mutect2, varscan2
- PIK3C2B | c.714C>G p.L238= | Silent (SNP) | VAF 223/715 reads (31%) | catalogued as COSV100914987; called by muse, mutect2, varscan2
- PIK3R1 | c.1530A>G p.E510= (on ENST00000521381 / NM_181523.3; = p.E240= on NM_181504.4) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99140482; called by muse, mutect2, varscan2
- PLXNB2 | c.345C>G p.L115= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100833818; called by muse, mutect2, varscan2
- POTEH | c.111G>T p.G37= | Silent (SNP) | VAF 365/831 reads (44%) | catalogued as COSV100624635; called by muse, mutect2, varscan2
- PSG6 | c.225C>G p.L75= | Silent (SNP) | VAF 77/184 reads (42%) | catalogued as COSV99413450; called by muse, mutect2, varscan2
- PTCHD3 | c.1365G>T p.G455= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV101438808; called by muse, mutect2
- RAB11FIP5 | c.1755G>T p.L585= | Silent (SNP) | VAF 97/279 reads (35%) | catalogued as COSV99241551; called by muse, varscan2
- RC3H2 | c.1482C>T p.N494= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs369650946; called by muse, mutect2, varscan2
- RET | c.411C>T p.C137= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV60697802; called by muse, mutect2, varscan2
- RORA | c.1167C>T p.D389= (on ENST00000335670 / NM_134261.3; = p.D414= on NM_002943.3) | Silent (SNP) | VAF 53/283 reads (19%) | catalogued as rs61760898; called by muse, mutect2, varscan2
- SEPTIN9 | c.981G>T p.S327= (on ENST00000427177 / NM_001113491.2; = p.S309= on NM_006640.4) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100217336; called by muse, mutect2, varscan2
- SLC36A2 | c.1218C>T p.V406= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100078861; called by muse, mutect2, varscan2
- SLC4A10 | c.1275T>C p.T425= (on ENST00000446997 / NM_001354461.2; = p.T395= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99762036; called by muse, mutect2, varscan2
- SLC6A1 | c.1435C>A p.R479= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs745529755, COSV55113671, COSV99822328; called by muse, mutect2, varscan2
- SMPD3 | c.99G>C p.R33= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99545199; called by muse, mutect2, varscan2
- SMURF2 | c.918T>C p.R306= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99300235; called by muse, mutect2
- SPNS2 | c.1296G>T p.G432= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100223399; called by muse, mutect2, varscan2
- SRGAP1 | c.600C>G p.V200= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100754173; called by muse, mutect2, varscan2
- SWI5 | c.348A>G p.V116= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100199524; called by muse, mutect2, varscan2
- TBL1X | c.1545T>A p.P515= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV99481999; called by muse, mutect2, varscan2
- TBX15 | c.906C>T p.F302= (on ENST00000369429 / NM_001330677.2; = p.F196= on NM_152380.3) | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as COSV99253478; called by muse, mutect2, varscan2
- THSD7B | c.399G>T p.T133= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs777573968, COSV55741660; called by muse, mutect2, varscan2
- TOR2A | c.822C>T p.N274= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs752866331, COSV100262649; called by muse, mutect2, varscan2
- TRIM14 | c.852C>G p.A284= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs777800386, COSV99271058; called by muse, mutect2
- TRMT13 | c.594T>C p.H198= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs758244108, COSV100923998; called by muse, mutect2, varscan2
- TTN | c.65031C>A p.A21677= (on ENST00000591111; = p.A14253= on NM_003319.4) | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100591387; called by muse, mutect2, varscan2
- TUBA3C | c.27G>T p.V9= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV67139274; called by muse, mutect2, varscan2
- UBR3 | c.3747A>G p.R1249= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99772989; called by muse, mutect2, varscan2
- UGT3A2 | c.1203A>T p.V401= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV99235937; called by muse, mutect2, varscan2
- VIP | c.405C>G p.T135= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV100923894; called by muse, mutect2, varscan2
- VNN2 | c.954T>A p.V318= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV100426683; called by muse, mutect2, varscan2
- ZNF101 | c.306C>T p.C102= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100543448; called by muse, mutect2, varscan2
- ZNF257 | c.1492C>A p.R498= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV101447992; called by muse, mutect2, varscan2
- ZNF697 | c.1290G>T p.T430= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as COSV101359984, COSV70284291; called by muse, mutect2, varscan2
- ZNF804A | c.645T>C p.S215= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV56451180, COSV56458592; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668462 G>T | 5'Flank (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- AL590867.2 | n.211C>T | RNA (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- HNF4A | c.1129+49G>T | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100290984, COSV100291353; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-36C>A | Intron (SNP) | VAF 13/20 reads (65%) | catalogued as COSV100024642, COSV100024722; called by muse, mutect2, varscan2
- MSLNL | c.37+1294C>A | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99135562; called by muse, mutect2
- NR1I2 | c.-23+462C>G | Intron (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100561421; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120743 T>G | 3'Flank (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- REXO1L1P | n.798C>A | RNA (SNP) | VAF 10/34 reads (29%) | catalogued as rs1470772089; called by muse, varscan2
- SLIT3 | c.198-12227C>A | Intron (SNP) | VAF 20/51 reads (39%) | catalogued as rs772103306, COSV100265067, COSV100265490; called by muse, mutect2, varscan2
- SORCS1 | c.3371+193_3371+203del | Intron (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- TOMM20 | c.121+718C>G | Intron (SNP) | VAF 9/174 reads (5%) | catalogued as COSV100783872; called by muse, mutect2
- WWC2 | c.*3825G>C | 3'UTR (SNP) | VAF 72/161 reads (45%) | catalogued as COSV100032755; called by muse, mutect2, varscan2
